Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A1QO, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A1QO-01A (Primary Tumor).

[page 1 of 2]
IIII/AA Discrepancy		☒

bw 3/16/11

Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

100-0-3 Carcinoma, papillary/tall cell 8344/3
Site: Thyroid, NOS C73.9 2H4/11 hr

Clinical Diagnosis & History:

year old male with thyroid mass, FNA- PTC.

Specimens Submitted:

- 1: SP: Subcutaneous lymph node
- 2: SP: Thyroid and isthmus, total thyroidectomy

DIAGNOSIS:

1. Lymph node, subcutaneous, excision:
-Benign fibroadipose tissue

Note: No lymph nodes are identified in the entirely submitted specimen

2. SP: Thyroid and isthmus, total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type
with tall cell features

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Isthmus

Tumor Size:

Greatest diameter is 2.2 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Invades:the extrathyroidal adipose tissue

Surgical Margins:

Tumor is present at the inked anterior margin

Tumor Multicentricity:

Microscopic foci present

[page 2 of 2]
Two foci of papillary microcarcinoma are noted in right and left lobes measuring 0.2 cm and 0.22 cm in greatest dimension respectively

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia
Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

Not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "Subcutaneous lymph node" and consists of a single fatty lymph node measuring 0.7 x 0.5 x 0.3 cm. The specimen is entirely submitted.

Summary of sections:

LN - lymph node

2). The specimen is received fresh, labeled "Total thyroidectomy and isthmus tumor" and consists of a previously sectioned (isthmus) thyroid weighing 17.5 g. The right lobe measures 3.7 x 2.2 x 1.4 cm, the left lobe measures 2.4 x 2.0 x 0.8 cm and the isthmus measures 4.3 x 2.6 x 1.2 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning the isthmus reveals a 2.2 x 1.8 x 1.1 cm well-circumscribed red-tan fleshy mass and a 1.3 cm cystic lesion adjacent or within the mass. The remaining thyroid parenchyma is red tan and beefy. Representative section of the specimen is submitted for a photograph has been taken. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

N - nodule

RL - right lobe

LL - left lobe

Summary of Sections:

Part 1: SP: Subcutaneous lymph node

Block	Sect. Site	PCs
1	LN	1

Part 2: SP: Thyroid and Isthmus, total thyroidectomy

Block	Sect. Site	PCs
3	LL	6
5	N	5
7	RL	8

Source: NCI Genomic Data Commons file 0c7cb39f-6446-4543-9f53-83c60c01a62e (TCGA-DJ-A1QO.39783E42-ABA0-4CF3-B6E8-B2CCC922FAF4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).